Somatic mutation profile of tumor specimen C3N-03045-01 (aliquot CPT0235910006) from CPTAC case C3N-03045, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 77.8 years (28,410 days).
Specimen C3N-03045-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36fff936-cc04-4fa7-a135-dc754df3cf62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03045-71 (Blood Derived Normal), aliquot CPT0235970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b367e8de-801b-4919-b657-551248364fb3

The open-access MAF lists 159 somatic variants for this specimen: 106 protein-altering or splice-affecting, 28 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 28, Intron 8, 5'UTR 6, RNA 5, Splice Site 4, Nonsense Mutation 4, Frame Shift Del 4, Splice Region 3, 3'UTR 2, 5'Flank 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1S | c.4798-2A>G p.X1600_splice | Splice Site (SNP) | VAF 42/155 reads (27%) | catalogued as rs1428157373; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BBS9 | c.1799G>A p.R600H (on ENST00000242067 / NM_001348036.1; = p.R560H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749018243, COSV54189065; called by muse, mutect2, varscan2
- C2orf78 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as rs190164698; called by muse, mutect2, varscan2
- CDH19 | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV50976882; called by muse, mutect2
- CDK20 | c.500+1G>A p.X167_splice | Splice Site (SNP) | VAF 138/335 reads (41%) | catalogued as rs762456005; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1587C>T p.L529= (on ENST00000357886 / NM_001365728.1; = p.L515= on NM_016082.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 52/121 reads (43%) | catalogued as rs989316323; called by mutect2, varscan2
- CNPY3 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430096184; called by muse, mutect2, varscan2
- CSMD3 | c.5182G>A p.D1728N (on ENST00000297405 / NM_001363185.1; = p.D1624N on NM_052900.3) | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as COSV52247900; called by muse, mutect2
- EDEM2 | c.751del p.A251Qfs*15 | Frame Shift Del (DEL) | VAF 30/224 reads (13%) | catalogued as COSV65713038, COSV65713626; called by mutect2, pindel*, varscan2
- EFCC1 | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 98/336 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.031); catalogued as rs567338824, COSV71401788; called by muse, mutect2, varscan2
- EHBP1L1 | c.4470G>T p.R1490= | Splice Region (SNP) | VAF 16/351 reads (5%) | catalogued as COSV58572546; called by muse, mutect2
- EVA1C | c.217T>A p.L73M | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55823430; called by muse, mutect2, varscan2
- FAM83E | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs752338055; called by muse, mutect2, varscan2
- FOXD4L5 | c.1045C>A p.R349S | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1378535617; called by mutect2, varscan2
- H3C8 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 93/393 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV59953250; called by muse, mutect2, varscan2
- IDO2 | c.166G>T p.A56S (on ENST00000389060; = p.A69S on NM_194294.2) | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58426977; called by muse, mutect2, varscan2
- IFT172 | c.3886G>A p.V1296M | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs757728167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS1 | c.4500del p.L1501Sfs*28 | Frame Shift Del (DEL) | VAF 54/293 reads (18%) | catalogued as rs746857576; called by mutect2, pindel, varscan2
- ITSN2 | c.4252G>A p.A1418T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs746407764; called by muse, mutect2
- KCNH4 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52922099; called by muse, mutect2, varscan2
- LRRTM4 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); catalogued as COSV101297716; called by muse, mutect2, varscan2
- MALRD1 | c.3363C>A p.N1121K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs572803248; called by muse, mutect2, varscan2
- MIEF1 | c.77A>G p.N26S | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs780678940; called by muse, mutect2, varscan2
- MSRA | c.599C>G p.T200S | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs765230071; called by muse, mutect2, varscan2
- NDST3 | c.806G>T p.R269M | Missense Mutation (SNP) | VAF 67/320 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56615291; called by muse, mutect2, varscan2
- NOMO2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs1376784721; called by mutect2, varscan2
- NTRK2 | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 133/620 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.18); catalogued as rs200807970, COSV52873671; called by muse, mutect2, varscan2
- NUP210L | c.2321G>T p.G774V | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.255); catalogued as rs745360824; called by muse, mutect2, varscan2
- NUP214 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100845374; called by muse, mutect2
- OR5D14 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 49/222 reads (22%) | catalogued as COSV100162038, COSV59457922; called by muse, mutect2, varscan2
- OTOF | c.3040G>A p.D1014N (on ENST00000272371 / NM_194248.3; = p.D267N on NM_004802.4) | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as rs199771991; called by muse, mutect2, varscan2
- PXDNL | c.4237G>T p.D1413Y | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.793); catalogued as COSV62486612; called by muse, mutect2, varscan2
- SEMA5B | c.2339C>T p.T780M | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1244097859; called by muse, mutect2, varscan2
- SI | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.898); catalogued as rs765504251; called by muse, mutect2, varscan2
- SLC12A8 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 90/415 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs375202810; called by muse, mutect2, varscan2
- SLC16A5 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 203/358 reads (57%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs1261274685; called by muse, mutect2, varscan2
- SLC28A2 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.842); catalogued as rs371217234, COSV61665602; called by muse, mutect2, varscan2
- SLC34A2 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs148403466; called by muse, mutect2, varscan2
- SLC36A1 | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183131678; called by muse, mutect2, varscan2
- SV2C | c.179C>A p.P60Q | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs758651691, COSV59213838; called by muse, mutect2, varscan2
- SYNE2 | c.11065A>G p.R3689G | Missense Mutation (SNP) | VAF 95/362 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59960552; called by muse, mutect2, varscan2
- TENM3 | c.7375C>T p.R2459W | Missense Mutation (SNP) | VAF 145/571 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1311377674, COSV69301240; called by muse, varscan2
- TEX13A | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV61143875; called by muse, mutect2, varscan2
- TNXB | c.11659G>A p.G3887S (on ENST00000647633; = p.G3640S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/973 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV100925973; called by muse, mutect2, varscan2
- TSPY8 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 53/401 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99819067; called by muse, mutect2, varscan2
- ZNF519 | c.543C>A p.Y181* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as rs760469885; called by muse, mutect2, varscan2
- ZNF729 | c.3108G>A p.M1036I | Missense Mutation (SNP) | VAF 83/351 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as COSV62604349; called by muse, mutect2, varscan2
- ADCY2 | c.753C>A p.H251Q | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ADCY5 | c.2357C>G p.S786C | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- AEBP2 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AGBL2 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); called by muse, mutect2
- AHCYL2 | c.929A>T p.D310V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ASB5 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, varscan2
- BACH2 | c.862A>T p.S288C | Missense Mutation (SNP) | VAF 115/431 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- BARX1 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 137/404 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRIX1 | c.773A>G p.H258R | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CBWD2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 381/673 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- CDH3 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 17/558 reads (3%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- CEP95 | c.714C>T p.D238= | Splice Region (SNP) | VAF 62/112 reads (55%) | called by muse, mutect2, varscan2
- CFAP47 | c.5422G>A p.E1808K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.85); PolyPhen benign (0.034); called by mutect2, varscan2
- CHD7 | c.8968A>G p.I2990V | Missense Mutation (SNP) | VAF 122/316 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COPS8 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 264/390 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- CR1L | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 54/356 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CTSK | c.811A>G p.S271G | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2S1 | c.864_867del p.N289Rfs*4 | Frame Shift Del (DEL) | VAF 35/147 reads (24%) | called by mutect2, pindel, varscan2
- DCST1 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 106/386 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DEPDC5 | c.1445+1G>A p.X482_splice | Splice Site (SNP) | VAF 51/183 reads (28%) | called by muse, mutect2, varscan2
- DMXL2 | c.3170A>T p.E1057V | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- DNAJC14 | c.1622_1624del p.Q541_G542delinsR | In Frame Del (DEL) | VAF 42/175 reads (24%) | called by mutect2, pindel, varscan2
- E2F7 | c.2735A>C p.*912Sext*42 | Nonstop Mutation (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- FEZF2 | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- GATA3 | c.173A>T p.N58I | Missense Mutation (SNP) | VAF 162/492 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLIM4 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- HKDC1 | c.448del p.G151Afs*2 | Frame Shift Del (DEL) | VAF 54/257 reads (21%) | called by mutect2, pindel, varscan2
- IFT74 | c.1235C>A p.S412Y | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- IGF1R | c.1286A>G p.Q429R | Missense Mutation (SNP) | VAF 134/463 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KRCC1 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.706); called by mutect2, varscan2
- LGI2 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LGR6 | c.1861G>A p.V621I (on ENST00000367278 / NM_001017403.1; = p.V569I on NM_021636.3) | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTBP4 | c.3688G>C p.E1230Q (on ENST00000308370 / NM_001042544.1; = p.E1193Q on NM_003573.2) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MAD1L1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP2 | c.5374C>T p.R1792* | Nonsense Mutation (SNP) | VAF 43/576 reads (7%) | called by muse, mutect2
- MUC17 | c.4419C>A p.S1473R | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.351); called by muse, mutect2
- MUC5B | c.13109C>T p.A4370V | Missense Mutation (SNP) | VAF 112/654 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NCEH1 | c.602A>T p.D201V (on ENST00000538775; = p.D161V on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NSD3 | c.3755C>G p.P1252R | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- OR2B11 | c.464G>T p.S155I | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR2C1 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 55/252 reads (22%) | called by muse, mutect2, varscan2
- OR4C46 | c.217T>A p.S73T | Missense Mutation (SNP) | VAF 109/537 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- OSCP1 | c.651-2A>G p.X217_splice (on ENST00000356637 / NM_001330493.1; = p.X207_splice on NM_145047.5) | Splice Site (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- P2RY1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 106/444 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PCLO | c.12533A>G p.Q4178R | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PHKA2 | c.2681T>C p.I894T | Missense Mutation (SNP) | VAF 11/311 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRAMEF18 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 154/1456 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, varscan2
- RBBP6 | c.17A>T p.Y6F | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RC3H2 | c.124T>A p.L42M | Missense Mutation (SNP) | VAF 108/511 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RECQL4 | c.3450dup p.P1151Afs*76 | Frame Shift Ins (INS) | VAF 160/470 reads (34%) | called by mutect2, pindel, varscan2
- RIN3 | c.2588G>A p.R863Q | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RSL1D1 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SEMA3C | c.860G>T p.R287M | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD2 | c.5252A>C p.K1751T | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SFPQ | c.415_417dup p.S139dup | In Frame Ins (INS) | VAF 10/38 reads (26%) | called by mutect2, varscan2
- SH3TC2 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TBC1D31 | c.2178G>T p.W726C | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TNRC6C | c.1844dup p.N615Kfs*8 | Frame Shift Ins (INS) | VAF 58/222 reads (26%) | called by mutect2, varscan2
- TUBGCP6 | c.2404A>T p.I802F | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- AKAP12 | c.1020C>T p.D340= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as rs747736451, COSV53571470; called by muse, mutect2, varscan2
- ANKRD7 | c.741T>C p.H247= | Silent (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.978G>A p.L326= | Silent (SNP) | VAF 10/292 reads (3%) | called by muse, mutect2
- ASB5 | c.675T>C p.A225= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV56671582; called by muse, mutect2
- BICD2 | c.1002C>G p.S334= | Silent (SNP) | VAF 62/293 reads (21%) | called by muse, mutect2, varscan2
- BIRC2 | c.1269C>T p.N423= | Silent (SNP) | VAF 89/253 reads (35%) | called by muse, mutect2, varscan2
- CAMK2B | c.309G>T p.V103= | Silent (SNP) | VAF 23/322 reads (7%) | called by muse, mutect2
- CASP4 | c.441C>T p.D147= | Silent (SNP) | VAF 44/282 reads (16%) | catalogued as rs750060240; called by muse, mutect2, varscan2
- CXorf21 | c.690G>A p.V230= | Silent (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- DLG5 | c.4083C>T p.G1361= | Silent (SNP) | VAF 49/250 reads (20%) | called by muse, mutect2, varscan2
- DNAH8 | c.9897C>T p.G3299= | Silent (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- IGFN1 | c.1278T>C p.Y426= (on ENST00000295591 / NM_001367841.1; = p.Y2883= on NM_001164586.2) | Silent (SNP) | VAF 115/355 reads (32%) | called by muse, mutect2, varscan2
- KCNH4 | c.444G>A p.G148= | Silent (SNP) | VAF 85/140 reads (61%) | catalogued as rs375796842; called by muse, mutect2, varscan2
- LINGO2 | c.1314G>A p.P438= | Silent (SNP) | VAF 79/195 reads (41%) | catalogued as rs200772912, COSV58059271; called by muse, mutect2, varscan2
- LOXL3 | c.1290C>T p.V430= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV51212323; called by muse, mutect2
- MGAT4A | c.1215G>C p.G405= | Silent (SNP) | VAF 61/197 reads (31%) | called by muse, mutect2, varscan2
- MTF2 | c.717A>G p.L239= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs928300147; called by muse, mutect2, varscan2
- MUSK | c.90C>A p.I30= | Silent (SNP) | VAF 28/195 reads (14%) | called by muse, mutect2, varscan2
- NYNRIN | c.3114C>T p.I1038= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as rs372328828; called by muse, mutect2, varscan2
- POR | c.1587G>A p.T529= | Silent (SNP) | VAF 10/190 reads (5%) | catalogued as rs371795413; ClinVar: uncertain significance; called by muse, mutect2
- RPS19BP1 | c.27C>G p.G9= | Silent (SNP) | VAF 68/255 reads (27%) | catalogued as COSV58180371; called by muse, mutect2, varscan2
- SAFB2 | c.1902C>T p.R634= | Silent (SNP) | VAF 59/178 reads (33%) | catalogued as rs371849776; called by muse, mutect2, varscan2
- STK32B | c.960A>G p.L320= | Silent (SNP) | VAF 36/146 reads (25%) | called by muse, mutect2, varscan2
- TROAP | c.831C>T p.A277= | Silent (SNP) | VAF 64/271 reads (24%) | called by muse, mutect2, varscan2
- WDFY3 | c.3073C>T p.L1025= | Silent (SNP) | VAF 60/203 reads (30%) | called by muse, mutect2, varscan2
- WTAP | c.984C>T p.Y328= | Silent (SNP) | VAF 66/326 reads (20%) | catalogued as rs1189934011; called by muse, mutect2, varscan2
- ZNF407 | c.3705A>T p.G1235= | Silent (SNP) | VAF 50/133 reads (38%) | called by muse, mutect2, varscan2
- ZNF780B | c.2082G>A p.A694= | Silent (SNP) | VAF 40/159 reads (25%) | catalogued as rs756485399, COSV55461732; called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793724 A>G | 3'Flank (SNP) | VAF 24/108 reads (22%) | catalogued as rs575445413; called by muse, mutect2, varscan2
- AFG3L2 | c.-113C>T | 5'UTR (SNP) | VAF 138/370 reads (37%) | called by muse, mutect2, varscan2
- BIRC8 | n.1203C>T | RNA (SNP) | VAF 72/292 reads (25%) | catalogued as COSV70346494; called by muse, mutect2, varscan2
- BSDC1 | c.1260+26G>T | Intron (SNP) | VAF 110/522 reads (21%) | called by muse, mutect2, varscan2
- CCDC171 | c.3753+1729G>C | Intron (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- CD7 | c.-1C>T | 5'UTR (SNP) | VAF 58/204 reads (28%) | called by muse, mutect2, varscan2
- CR1 | c.487+15135G>A | Intron (SNP) | VAF 114/504 reads (23%) | catalogued as rs367704854; called by muse, mutect2, varscan2
- CYP21A1P | chr6:32009151 C>T | 3'Flank (SNP) | VAF 18/151 reads (12%) | catalogued as rs758452613; called by mutect2, varscan2
- EPB41L4A | chr5:112420395 C>G | 5'Flank (SNP) | VAF 58/154 reads (38%) | catalogued as rs1198196979; called by muse, mutect2, varscan2
- FAR2 | c.190-1866G>A | Intron (SNP) | VAF 32/190 reads (17%) | catalogued as rs549029646, COSV99479802; called by muse, mutect2, varscan2
- FZD4 | c.-28G>T | 5'UTR (SNP) | VAF 16/68 reads (24%) | catalogued as rs1315666390; called by muse, varscan2
- HAL | c.-1del | 5'UTR (DEL) | VAF 57/250 reads (23%) | called by mutect2, pindel, varscan2
- IL10 | c.*26C>T | 3'UTR (SNP) | VAF 65/291 reads (22%) | called by muse, mutect2, varscan2
- KRT8P11 | n.861G>A | RNA (SNP) | VAF 179/397 reads (45%) | called by muse, mutect2, varscan2
- MST1L | n.1066C>A | RNA (SNP) | VAF 85/825 reads (10%) | catalogued as rs1245870981; called by muse, mutect2, varscan2
- NAA60 | c.-149T>G | 5'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- NDUFA7 | c.-13T>C | 5'UTR (SNP) | VAF 40/157 reads (25%) | called by muse, mutect2, varscan2
- OR10D1P | n.196G>A | RNA (SNP) | VAF 117/568 reads (21%) | called by muse, mutect2, varscan2
- OR51T1 | chr11:4881850 A>G | 5'Flank (SNP) | VAF 32/110 reads (29%) | catalogued as COSV100434342; called by muse, varscan2
- PDE4DIP | c.2904+303del | Intron (DEL) | VAF 14/83 reads (17%) | called by mutect2, pindel, varscan2
- PDPR | c.1868-352C>T | Intron (SNP) | VAF 11/156 reads (7%) | catalogued as rs1320039543; called by muse, mutect2
- PLCD1 | c.*109C>T | 3'UTR (SNP) | VAF 75/220 reads (34%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.-40+11341C>G | Intron (SNP) | VAF 84/347 reads (24%) | called by muse, mutect2, varscan2
- PRDM16-DT | n.1019+67C>T | Intron (SNP) | VAF 55/220 reads (25%) | called by muse, mutect2, varscan2
- SNORD115-5 | n.36G>T | RNA (SNP) | VAF 113/498 reads (23%) | called by muse, mutect2, varscan2
